Somatic mutation profile of tumor specimen TCGA-KL-8325-01A (aliquot TCGA-KL-8325-01A-11D-2310-10) from TCGA case TCGA-KL-8325, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 56.9 years (20,768 days).
Specimen TCGA-KL-8325-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e0d9879-a7c5-4176-a34b-019edab6d569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8325-11A (Solid Tissue Normal), aliquot TCGA-KL-8325-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4e41360-23bb-4cd0-9676-073f4c098e6b

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Intron 2, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACBD4 | c.573+1G>A p.X191_splice | Splice Site (SNP) | VAF 67/71 reads (94%) | catalogued as COSV100416356; called by muse, mutect2, varscan2
- C1orf167 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.39); catalogued as rs1476147480, COSV100453841; called by muse, mutect2
- CNDP1 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 120/265 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.393); catalogued as rs1268524661; called by muse, mutect2, varscan2
- FAM20C | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs1035232018, COSV100570628; called by muse, mutect2
- MYT1 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV60504585; called by muse, mutect2, varscan2
- NRP2 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55930279, COSV99785994; called by muse, mutect2
- SOX13 | c.1352A>G p.N451S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99690082; called by muse, mutect2, varscan2
- SREK1IP1 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV101536196; called by muse, mutect2
- ZNF560 | c.1010T>A p.V337E | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.069); catalogued as COSV56868320; called by muse, mutect2
- HAS3 | c.1409G>A p.G470D | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MECOM | c.861T>G p.H287Q (on ENST00000468789 / NM_001105078.4; = p.H475Q on NM_004991.4) | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2
- PLEKHH1 | c.3804C>A p.Y1268* | Nonsense Mutation (SNP) | VAF 69/148 reads (47%) | called by muse, mutect2, varscan2
- UBQLN1 | c.90_93del p.S31Rfs*6 | Frame Shift Del (DEL) | VAF 13/14 reads (93%) | called by mutect2, varscan2*
- AL592490.1 | c.93A>C p.L31= | Silent (SNP) | VAF 7/147 reads (5%) | catalogued as COSV101308311, COSV69424627; called by muse, mutect2
- ALDH1A3 | c.243C>A p.A81= | Silent (SNP) | VAF 62/128 reads (48%) | called by muse, mutect2, varscan2
- APOBEC1 | c.657G>A p.P219= | Silent (SNP) | VAF 8/180 reads (4%) | catalogued as rs1031475367, COSV57548887; called by muse, mutect2
- FKBP9 | c.903G>A p.R301= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV99640618; called by muse, mutect2, varscan2
- INVS | c.813C>T p.V271= | Silent (SNP) | VAF 71/81 reads (88%) | called by muse, mutect2, varscan2
- CACNA1C | c.4727-11C>T | Intron (SNP) | VAF 52/108 reads (48%) | called by muse, mutect2, varscan2
- RBM33 | c.739+54A>G | Intron (SNP) | VAF 14/172 reads (8%) | catalogued as rs757771209; called by muse, mutect2
